Gene-level copy-number profile of tumor specimen TCGA-EY-A210-01A from TCGA case TCGA-EY-A210, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 82.4 years (30,095 days).
Specimen TCGA-EY-A210-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a24cc805-6f92-4528-9113-e6d4dec34138.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A210-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc98d1ea-2088-4638-b78d-06ae7ce56386

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 10,637; copy number 2: 42,957; copy number 3: 4,329; copy number 4: 1,247; copy number 5: 203; copy number 6: 28; copy number 7: 206; copy number 8: 167; copy number 13: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A210-01A-11D-A160-01): tumor purity 0.87, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:24,919,389–25,261,066, 16 genes (within-gene range 0–1): ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 621 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:104,998,406–105,618,991, 3 genes, copy number 6: AL591888.1, CDK4P1, LINC01676.
- chr1:106,780,223–107,965,180, 9 genes, copy number 5 (within-gene range 2–5): AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852.
- chr1:118,614,333–118,713,678, 2 genes, copy number 6: PSMC1P12, AL139148.1.
- chr1:180,509,380–180,566,523, 2 genes, copy number 6: OVAAL, Y_RNA.
- chr9:126,914,774–128,163,924, 48 genes, copy number 7 (within-gene range 4–7): RALGPS1, ANGPTL2, AL450263.1, GARNL3, AL450263.2, AL445222.1, SLC2A8, ZNF79, RPL12, SNORA65, LRSAM1, Y_RNA, NIBAN2, STXBP1, AL162426.1, PTRH1, MIR3911, CFAP157, TTC16, TOR2A, SH2D3C, AL162586.2, CDK9, MIR3960, MIR2861, FPGS, ENG, AL162586.1, Y_RNA, RNA5SP296, AK1, AL157935.2, MIR4672, ST6GALNAC6, ST6GALNAC4, PIP5KL1, AL157935.1, DPM2, FAM102A, AL360268.2, NAIF1, SLC25A25, AL360268.1, SLC25A25-AS1, PTGES2, PTGES2-AS1, LCN2, C9orf16.
- chr11:46,277,662–46,386,608, 5 genes, copy number 6 (within-gene range 2–6): CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:46,428,653–46,451,889, 3 genes, copy number 6: AC024293.1, MIR3160-1, MIR3160-2.
- chr12:47,699,401–47,943,048, 16 genes, copy number 5 (within-gene range 2–5): AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2.
- chr13:23,498,796–28,138,193, 112 genes, copy number 7 (broad region; genes not listed).
- chr13:82,778,208–84,563,236, 15 genes, copy number 8: AL445255.1, GYG1P2, AL512782.1, RNU6-67P, AL353688.1, SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1, MTND4P1, MTND5P3, LINC00333.
- chr13:96,941,281–103,444,968, 121 genes, copy number 5 (broad region; genes not listed).
- chr16:15,358,978–21,550,373, 174 genes, copy number 7–13 (broad region; genes not listed).
- chr16:22,297,375–22,613,483, 13 genes, copy number 6 (within-gene range 1–6): POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B, RRN3P3, SMG1P1, NPIPB5, AC106788.1, OTOAP1, AC009021.2, AC009021.1.
- chr17:20,743,333–21,641,536, 41 genes, copy number 7: RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1.
- chr20:31,257,664–32,439,319, 56 genes, copy number 5: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:32,449,755–32,453,607, 1 gene, copy number 5: AL034550.1.

Autosomal genes at a single copy (total copy number 1): 10,637. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
